Somatic mutation profile of tumor specimen TCGA-JY-A6FE-01A (aliquot TCGA-JY-A6FE-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 49.6 years (18,105 days).
Specimen TCGA-JY-A6FE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b74887d-add2-47b1-843a-cf3957fa0493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FE-10A (Blood Derived Normal), aliquot TCGA-JY-A6FE-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50eecab1-f206-4e73-87fa-637e23c4206c

The open-access MAF lists 60 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8A1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748975781; called by muse, mutect2, varscan2
- CAMSAP1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs765465088; called by muse, mutect2, varscan2
- CREBBP | c.2863C>T p.Q955* | Nonsense Mutation (SNP) | VAF 31/37 reads (84%) | catalogued as COSV52113388; called by muse, mutect2, varscan2
- GJB7 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756299568; called by muse, mutect2, varscan2
- KCNJ16 | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV99387969; called by muse, mutect2, varscan2
- MTRF1 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53481825; called by muse, mutect2, varscan2
- OR5C1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs764398782; called by muse, mutect2, varscan2
- PCDHGB6 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV53937573; called by muse, mutect2, varscan2
- PRPF18 | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs752453925, COSV66074312; called by muse, mutect2, varscan2
- RGS17 | c.108C>G p.C36W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV52808797; called by muse, mutect2, varscan2
- SALL4 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as rs755288586, COSV53850429; called by muse, mutect2, varscan2
- SOX13 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs181852086; called by muse, mutect2, varscan2
- TACC1 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as COSV52526836; called by muse, mutect2, varscan2
- THBS2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759210002, COSV64677175; called by muse, mutect2, varscan2
- ZFHX3 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.595); catalogued as rs748777710, COSV51717468, COSV51734396; called by muse, mutect2, varscan2
- ASF1B | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CACNB3 | c.389_395del p.K130Sfs*13 | Frame Shift Del (DEL) | VAF 48/70 reads (69%) | called by mutect2, pindel, varscan2
- CD36 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDKN1A | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- CNOT6L | c.329A>G p.N110S (on ENST00000504123 / NM_001286790.2; = p.N105S on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- COPA | c.1190del p.P397Lfs*20 | Frame Shift Del (DEL) | VAF 43/142 reads (30%) | called by mutect2, pindel, varscan2
- DNAH5 | c.9972T>G p.D3324E | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.12734C>T p.A4245V (on ENST00000361203 / NM_001374722.1; = p.A1833V on NM_015548.5) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENPP1 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FAAH2 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- FERMT1 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GID8 | c.100A>T p.M34L | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- HMCN1 | c.14472C>G p.S4824R | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- IBSP | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICAM5 | c.905G>A p.C302Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGF2R | c.4955G>A p.C1652Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF2 | c.2207T>A p.I736N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- LTBP1 | c.2396-2A>C p.X799_splice (on ENST00000404816 / NM_206943.4; = p.X473_splice on NM_000627.4) | Splice Site (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- MFSD9 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- MYO16 | c.2176_2177insT p.R726Lfs*9 | Frame Shift Ins (INS) | VAF 52/170 reads (31%) | called by mutect2, pindel, varscan2
- NALCN | c.3057+2T>C p.X1019_splice | Splice Site (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- NPAS4 | c.575G>C p.C192S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRDX1 | c.571A>C p.S191R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PTPRZ1 | c.5503-2A>C p.X1835_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- QSER1 | c.4637A>G p.K1546R (on ENST00000399302; = p.K1675R on NM_001076786.3) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3RF1 | c.483_485del p.I162del | In Frame Del (DEL) | VAF 36/65 reads (55%) | called by pindel, varscan2
- SKAP1 | c.372T>G p.F124L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STYXL1 | c.44dup p.L16Pfs*28 | Frame Shift Ins (INS) | VAF 42/125 reads (34%) | called by mutect2, pindel, varscan2
- SUN1 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by mutect2, varscan2
- TP53 | c.414_427del p.K139Afs*5 | Frame Shift Del (DEL) | VAF 21/26 reads (81%) | called by mutect2, varscan2
- VPS37C | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WRN | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.11352G>A p.T3784= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1460065428; called by muse, mutect2, varscan2
- EXOSC7 | c.531G>A p.S177= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs773602045; called by muse, mutect2, varscan2
- FAM234B | c.1494C>G p.A498= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs374898629; called by muse, mutect2, varscan2
- HIF3A | c.1476C>G p.P492= (on ENST00000377670 / NM_152795.4; = p.P423= on NM_022462.4) | Silent (SNP) | VAF 33/46 reads (72%) | catalogued as COSV52200054; called by muse, mutect2, varscan2
- KIAA1217 | c.1362A>G p.K454= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs369181477; called by muse, mutect2
- LARGE1 | c.324T>A p.T108= | Silent (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- LMNB1 | c.216C>T p.G72= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs1034786910; called by muse, mutect2, varscan2
- PCLO | c.5082C>T p.D1694= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs367988765, COSV100436349; called by muse, mutect2, varscan2
- RNF40 | c.2011C>T p.L671= | Silent (SNP) | VAF 24/31 reads (77%) | called by muse, mutect2, varscan2
- SOCS4 | c.216A>C p.S72= | Silent (SNP) | VAF 40/54 reads (74%) | called by muse, mutect2, varscan2
- SYT5 | c.954A>G p.Q318= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1182437229; called by muse, mutect2, varscan2
- WDR45B | c.720G>A p.Q240= | Silent (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- ZW10 | c.475T>C p.L159= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1410301217; called by muse, mutect2, varscan2
